Somatic mutation profile of tumor specimen TCGA-AX-A3FV-01A (aliquot TCGA-AX-A3FV-01A-11D-A228-09) from TCGA case TCGA-AX-A3FV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 62.3 years (22,752 days).
Specimen TCGA-AX-A3FV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 481683e0-fe95-495d-8182-c981cfeeb2dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3FV-10A (Blood Derived Normal), aliquot TCGA-AX-A3FV-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b40a5e2-5194-4d64-981a-29ecb9858cfb

The open-access MAF lists 100 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 26, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 21/24 reads (88%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC005833.1 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99362353; called by muse, mutect2, varscan2
- AFF3 | c.1601G>C p.R534T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417076, COSV57856882; called by muse, mutect2, varscan2
- ALPK2 | c.3805C>A p.P1269T | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100863938; called by muse, mutect2, varscan2
- ASXL2 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV99709942; called by muse, mutect2, varscan2
- ATP2A2 | c.1048T>G p.S350A | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100428313; called by mutect2, varscan2
- BLCAP | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs773830800, COSV99289931; called by muse, mutect2, varscan2
- CACHD1 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99261181; called by muse, mutect2, varscan2
- CACNA1B | c.5690T>C p.L1897P | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99494499; called by muse, mutect2, varscan2
- CDK14 | c.598A>C p.I200L (on ENST00000380050 / NM_001287135.2; = p.I182L on NM_012395.3) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99723339; called by muse, mutect2, varscan2
- CHD4 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100537143; called by muse, mutect2, varscan2
- CSMD1 | c.4482C>G p.F1494L (on ENST00000520002; = p.F1493L on NM_033225.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1229674571, COSV100141950, COSV59323740; called by muse, mutect2, varscan2
- CSMD2 | c.6788G>T p.S2263I | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99584490; called by muse, mutect2, varscan2
- CTTNBP2 | c.1892T>C p.L631P | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99352705; called by muse, mutect2, varscan2
- CUL3 | c.1485+2T>C p.X495_splice | Splice Site (SNP) | VAF 54/79 reads (68%) | catalogued as COSV100023534; called by muse, mutect2, varscan2
- CYP1A1 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs201651069, COSV65698292; called by muse, mutect2, varscan2
- DTNA | c.1741T>A p.S581T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV99310330; called by muse, mutect2, varscan2
- EDEM3 | c.853+2T>G p.X285_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100544768; called by muse, mutect2, varscan2
- ELAPOR2 | c.2536G>T p.A846S (on ENST00000450689 / NM_001142749.3; = p.A679S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV99787973; called by muse, mutect2, varscan2
- FAM83D | c.1372T>C p.S458P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99464889; called by muse, mutect2, varscan2
- FGF5 | c.460-1G>A p.X154_splice | Splice Site (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100427758; called by muse, mutect2, varscan2
- FRMPD2 | c.682T>A p.C228S | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100563403; called by muse, varscan2
- GALNT3 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101204868; called by muse, mutect2, varscan2
- GBP2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs369681409; called by muse, mutect2, varscan2
- H2AC4 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as COSV52519865; called by muse, mutect2
- HGSNAT | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV101107781; called by muse, mutect2, varscan2
- HIPK1 | c.3579T>G p.I1193M (on ENST00000369558 / NM_001369806.1; = p.I799M on NM_181358.2) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV100478249; called by muse, mutect2, varscan2
- IRGC | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs558557281, COSV54983636; called by muse, mutect2, varscan2
- JAK3 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101512864; called by muse, mutect2, varscan2
- KDM2B | c.1748G>C p.G583A | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.572); catalogued as COSV100997067; called by muse, mutect2, varscan2
- KMT2C | c.2918G>T p.R973I | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100064726; called by muse, mutect2
- KRTAP8-1 | c.190T>C p.*64Rext*8 | Nonstop Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100297771; called by muse, mutect2, varscan2
- LUZP2 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV61220676; called by muse, mutect2, varscan2
- LUZP2 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100418560, COSV61206627; called by muse, mutect2
- MEF2B | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs779592456, COSV50764311; called by muse, mutect2
- MRPL15 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99477467; called by muse, mutect2, varscan2
- MUC16 | c.42345G>C p.Q14115H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as COSV101109439; called by muse, mutect2, varscan2
- MYO15A | c.6938G>C p.S2313T | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99230686; called by muse, mutect2, varscan2
- NBEAL1 | c.6613G>A p.A2205T | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101355340; called by muse, mutect2, varscan2
- NCOR1 | c.5152C>T p.R1718W | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373216507; called by muse, mutect2, varscan2
- NOX5 | c.1907T>G p.F636C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99533064; called by muse, mutect2, varscan2
- NPC1 | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV52575905, COSV52579752; called by muse, mutect2, varscan2
- OR4B1 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100535457; called by muse, mutect2, varscan2
- OR4D11 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755431598, COSV57585431; called by muse, mutect2, varscan2
- OTOGL | c.2376C>A p.N792K (on ENST00000547103; = p.N783K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV101508994; called by muse, mutect2, varscan2
- OTUB1 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.959); catalogued as rs1169307056, COSV100034206; called by muse, mutect2, varscan2
- P4HA3 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753221508, COSV59040945; called by muse, mutect2, varscan2
- PCIF1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100975943; called by muse, mutect2, varscan2
- PDE4DIP | c.5600G>A p.R1867H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs375617654; called by muse, mutect2, varscan2
- REN | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99689351; called by muse, mutect2, varscan2
- RING1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs543164083, COSV100761701; called by muse, mutect2, varscan2
- RREB1 | c.1244T>C p.F415S | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV100619045; called by muse, mutect2, varscan2
- RYR2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs745569662, COSV63665961, COSV63668687; called by muse, mutect2, varscan2
- SCARA3 | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV100106238; called by muse, mutect2, varscan2
- SCIN | c.1699G>C p.E567Q (on ENST00000297029 / NM_001112706.3; = p.E320Q on NM_033128.3) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV51701132; called by muse, mutect2, varscan2
- SEMA7A | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV99984497; called by muse, mutect2, varscan2
- SH3RF3 | c.259T>C p.C87R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV100512179; called by muse, mutect2, varscan2
- SLAIN1 | c.1574C>G p.S525W (on ENST00000466548; = p.S262W on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57387419, COSV99934893; called by muse, mutect2, varscan2
- SLC26A9 | c.1382T>A p.L461Q | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100535881; called by muse, mutect2, varscan2
- SLC9C1 | c.2210G>C p.R737T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV99997036, COSV99997100; called by muse, mutect2, varscan2
- SPATA31A1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 126/233 reads (54%) | catalogued as rs1388438641; called by muse, mutect2, varscan2
- TATDN1 | c.353A>T p.D118V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99413120; called by muse, mutect2, varscan2
- TIE1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as rs765436299, COSV100991923; called by muse, mutect2, varscan2
- TP53BP2 | c.1713C>G p.D571E (on ENST00000343537 / NM_001031685.3; = p.D442E on NM_005426.2) | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100636483; called by muse, mutect2, varscan2
- TRIM51 | c.504G>C p.W168C | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55264441, COSV55267750, COSV99791988; called by muse, mutect2, varscan2
- VWC2L | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs371952173; called by muse, mutect2, varscan2
- ZAN | c.2523A>T p.E841D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100768964, COSV100770268; called by muse, mutect2, varscan2
- ZNF235 | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.348); catalogued as rs1420299794, COSV99349177; called by muse, mutect2, varscan2
- ATP2A2 | c.1047del p.S350Qfs*35 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, varscan2
- FOXD4L4 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- HSPB8 | c.206_220delinsGG p.V69Gfs*28 | Frame Shift Del (DEL) | VAF 47/67 reads (70%) | called by pindel, varscan2*
- RB1 | c.1358_1359insATTCCA p.Y453delins* | Nonsense Mutation (INS) | VAF 15/21 reads (71%) | called by mutect2, varscan2
- TUSC3 | c.508del p.R170Efs*9 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- ABCB11 | c.3849G>A p.A1283= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs566857672, COSV55591440; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRV1 | c.6549A>G p.K2183= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV101315309; called by muse, mutect2, varscan2
- BCL9L | c.4110T>A p.T1370= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99418340; called by muse, mutect2, varscan2
- CREB1 | c.21C>G p.A7= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100783522, COSV62065216, COSV62066741; called by muse, mutect2, varscan2
- CRISP1 | c.609A>G p.E203= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100236526; called by muse, mutect2, varscan2
- DCDC1 | c.2319G>T p.L773= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV100662507; called by muse, mutect2, varscan2
- DGKG | c.1410G>A p.G470= | Silent (SNP) | VAF 44/77 reads (57%) | catalogued as rs751990823, COSV99402141; called by muse, mutect2, varscan2
- EPS15 | c.1326T>G p.T442= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100869378; called by muse, mutect2, varscan2
- HOMER2 | c.1056C>A p.T352= (on ENST00000304231 / NM_199330.3; = p.T341= on NM_004839.4) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100420131; called by muse, mutect2, varscan2
- IGKV1-6 | c.138G>C p.R46= | Silent (SNP) | VAF 58/192 reads (30%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.108A>G p.G36= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as rs762127046; called by muse, mutect2, varscan2
- KRTAP6-3 | c.27T>C p.C9= | Silent (SNP) | VAF 55/232 reads (24%) | catalogued as COSV101196454; called by muse, mutect2, varscan2
- NPAP1 | c.2208C>T p.S736= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs758464262, COSV61505318; called by muse, mutect2, varscan2
- NYAP2 | c.597G>A p.P199= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs529456486, COSV56003344, COSV56006863, COSV56010363; called by muse, mutect2, varscan2
- OR10T2 | c.252C>G p.V84= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100554765; called by muse, mutect2, varscan2
- POTEE | c.2814G>A p.K938= | Silent (SNP) | VAF 45/256 reads (18%) | catalogued as COSV100386536; called by muse, mutect2, varscan2
- PRAMEF12 | c.93G>T p.L31= | Silent (SNP) | VAF 38/216 reads (18%) | catalogued as rs756470250, COSV100742921; called by muse, mutect2
- PTCD2 | c.627T>A p.I209= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100348673; called by muse, mutect2, varscan2
- PTPN4 | c.390T>C p.I130= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99749260; called by muse, mutect2, varscan2
- PTPRH | c.1011T>C p.D337= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV99670579; called by muse, mutect2, varscan2
- RPL7L1 | c.234C>G p.L78= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100491604; called by muse, mutect2, varscan2
- SARDH | c.48C>G p.R16= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100060347; called by muse, mutect2, varscan2
- SP8 | c.9C>G p.A3= (on ENST00000361443 / NM_198956.4; = p.A21= on NM_182700.6) | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1380643851, COSV100815224, COSV63867041; called by muse, mutect2, varscan2
- TTN | c.99567C>T p.S33189= (on ENST00000591111; = p.S25765= on NM_003319.4) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs199661082, COSV100589436; called by muse, varscan2
- TTN | c.6237A>G p.K2079= (on ENST00000591111; = p.K2033= on NM_003319.4) | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100589438; called by muse, mutect2, varscan2
- ZNF883 | c.153C>G p.T51= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV101432494; called by muse, mutect2, varscan2
- PDE4D | c.455+124706T>C | Intron (SNP) | VAF 25/51 reads (49%) | catalogued as rs759080805, COSV100504218; called by muse, mutect2, varscan2
